Gene-level copy-number profile of tumor specimen TCGA-DD-A4NA-01A from TCGA case TCGA-DD-A4NA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.4 years (24,603 days).
Specimen TCGA-DD-A4NA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.a3e23396-cc09-4e7e-b6cd-b012bd010013.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A4NA-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c13343b-65db-4a4d-9041-0e2b2501dc47

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 2: 9,288; copy number 3: 5,562; copy number 4: 38,674; copy number 5: 5,423; copy number 6: 531; copy number 7: 296; copy number 8: 17; copy number 11: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A4NA-01A-11D-A25U-01): tumor purity 0.63, ploidy 3.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:98,606,833–99,070,792, 8 genes: SEPTIN7P7, ANKS6, AL807776.1, GALNT12, AL136084.1, NME2P3, COL15A1, AL136084.2.
- chr9:135,702,185–136,245,812, 10 genes (within-gene range 0–3): KCNT1, CAMSAP1, AL355574.1, UBAC1, NACC2, LINC02846, TMEM250, AL138781.1, LHX3, QSOX2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:130,790,208–130,791,724, 1 gene, copy number 11: AC016831.5.
- chr7:130,822,868–130,843,725, 3 genes, copy number 11: AC016831.2, H4P1, AC016831.3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
